CGCI case BLGSP-71-23-00368 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a51944ff-a92a-40aa-8c4c-1e90ae85a28c

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 4.1 years (1,500 days); Year of diagnosis: 2015; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,158 days (3.2 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone marrow / Colon, NOS / Kidney, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: BFM-95; Days to treatment start: -2 days; Days to treatment end: 141 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Dexamethasone + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: -2 days; Days to treatment end: 141 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Days to treatment start: -2 days; Days to treatment end: 141 days; Number of cycles: 6.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 4.
- Days to follow up: 1,158 days (3.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 5168 [Blood test normal range upper: 618].

Other clinical attributes
- Day 0: Weight: 15.5 kg; Height: 106 cm; BMI: 13.8.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-23-00368-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00368-01-CD20: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-CD3: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-BCL6: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-BCL2: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-CD10: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-Ki67: Tissue microarray coordinates: E1,C4,B5.
  Slide BLGSP-71-23-00368-01-HE-1: Tissue microarray coordinates: E1,C4,B5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Weight kg at diagnosis: 15.5 kg; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Days from index date to tumor sample procurement: -3; Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Colon; Extranodal involvement site: Kidney.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 5168.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
